Gene-level copy-number profile of tumor specimen TCGA-VS-A9UL-01A from TCGA case TCGA-VS-A9UL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 79.5 years (29,033 days).
Specimen TCGA-VS-A9UL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.32bb6048-a023-4822-94f9-584c492b16fb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9UL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/48305cbb-74f1-4884-8e46-126c0ff20ab7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 7,420; copy number 2: 12,077; copy number 3: 23,300; copy number 4: 9,633; copy number 5: 2,672; copy number 6: 1,917; copy number 7: 946; copy number 8: 111; copy number 10: 1,006; copy number 13: 710; copy number 19: 8; copy number 93: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9UL-01A-11D-A42N-01): tumor purity 0.84, ploidy 5.08, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,795 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:133,661,998–133,754,576, 1 gene, copy number 8 (within-gene range 4–8): INHCAP.
- chr3:133,710,076–198,222,513, 1,116 genes, copy number 8–10 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 13 (broad region; genes not listed).
- chr6:85,427,453–152,637,801, 946 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr11:102,746,968–102,836,766, 1 gene, copy number 19 (within-gene range 3–19): WTAPP1.
- chr11:102,789,919–102,955,732, 7 genes, copy number 19: MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13.
- chr17:39,461,486–39,747,291, 14 genes, copy number 93 (within-gene range 4–93): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.

Autosomal genes at a single copy (total copy number 1): 7,417. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
